Gene-level copy-number profile of tumor specimen HCM-SANG-1327-C18-01A-01D-A80T-32 from HCMI case HCM-SANG-1327-C18, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; Tumor grade: G2.
Specimen HCM-SANG-1327-C18-01A-01D-A80T-32: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 0486e0b9-ca48-4cbe-9a60-80f701139ea0.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-SANG-1327-C18-10A-01D-A80T-32 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,252 have no estimate.
https://portal.gdc.cancer.gov/files/210b745b-06d1-4e40-a76a-0cadd870c73f

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 31; copy number 1: 20; copy number 2: 4,102; copy number 3: 254; copy number 4: 30,897; copy number 5: 1,827; copy number 6: 14,908; copy number 7: 401; copy number 8: 5,168; copy number 9: 95; copy number 10: 121; copy number 11: 291; copy number 12: 37; copy number 13: 118; copy number 15: 98; copy number 18: 3.

Homozygous deletions (total copy number 0; autosomes only): 31 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,498,785–143,500,512, 2 genes: AC239859.2, LINC02799.
- chr9:39,748,514–39,810,097, 2 genes: GLIDR, BX664615.1.
- chr9:40,223,285–40,266,845, 2 genes (within-gene range 0–4): ANKRD20A2P, RNU6-1269P.
- chr9:41,276,280–41,764,175, 18 genes: PTGER4P2-CDK2AP2P2, CDK2AP2P1, MYO5BP1, AL354718.2, CDRT15P6, AL354718.1, AL591926.3, SNORA70, RN7SL565P, AL591926.7, AL591926.6, AL591926.5, AL591926.2, FAM242F, Y_RNA, AL591926.1, AL591926.4, AL162731.1.
- chr9:64,878,790–64,889,063, 2 genes: AC125634.1, RNU6-1293P.
- chr17:18,450,244–18,494,945, 5 genes (within-gene range 0–1): KRT16P4, AL353997.1, AL353997.4, TNPO1P2, LGALS9C.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 763 genes in 13 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:25,242,249–25,338,213, 1 gene, copy number 9 (within-gene range 4–9): RSRP1.
- chr1:25,266,102–25,330,445, 3 genes, copy number 9: AL031432.2, RHD, SDHDP6.
- chr1:143,846,097–143,905,966, 4 genes, copy number 11 (within-gene range 4–11): AC239798.2, FCGR1CP, H2BP2, H3-2.
- chr7:37,032–2,844,308, 73 genes, copy number 9 (within-gene range 8–9) (broad region; genes not listed).
- chr9:39,886,861–39,892,895, 3 genes, copy number 18: RN7SL763P, SNORA70, CR769767.1.
- chr13:113,759,226–114,337,626, 18 genes, copy number 9: TMEM255B, GAS6-AS1, GAS6, GAS6-DT, BX072579.1, LINC00454, BX072579.2, LINC00452, LINC00565, RASA3, RASA3-IT1, CDC16, MIR548AR, MIR4502, UPF3A, CLCP2, CHAMP1, LINC01054.
- chr20:16,177,933–20,854,642, 92 genes, copy number 13–15 (broad region; genes not listed).
- chr20:22,263,065–23,711,406, 48 genes, copy number 10: LINC01427, AL049737.1, AL121912.1, AL133464.1, LINC00261, FOXA2, LNCNEF, LINC01747, AL158175.1, KRT18P3, CYB5AP4, AL353132.1, AL049651.1, AL049651.2, SSTR4, THBD, AL118508.3, CD93, LINC00656, AL118508.2, RNA5SP478, AL118508.1, AL390037.1, NXT1-AS1, NXT1, LINC01431, GZF1, NAPB, RNA5SP479, CSTL1, CST11, AL096677.1, Y_RNA, CST12P, AL109954.1, AL109954.2, CST8, CST13P, CST9LP1, CST9L, CST9LP2, CST9, CST3, AL121894.2, AL121894.1, AL121894.3, CST4, CST2P1.
- chr20:24,469,629–24,666,616, 1 gene, copy number 10 (within-gene range 8–10): SYNDIG1.
- chr20:24,679,547–25,919,681, 38 genes, copy number 10–11: AL049594.1, AL035661.1, CST7, APMAP, RNU6-1257P, AL035661.2, ACSS1, AL080312.2, VSX1, AL080312.1, AL035252.2, AL035252.1, ENTPD6, Y_RNA, AL035252.4, AL035252.3, AL121772.1, PYGB, AL121772.2, AL121772.3, ABHD12, PPIAP2, GINS1, NINL, RNU6ATAC17P, NANP, ZNF337-AS1, RN7SL594P, MED28P7, ZNF337, AL031673.1, AL390198.1, VN1R108P, FAM182B, BSNDP1, AL390198.2, BSNDP2, CFTRP1.
- chr20:30,484,925–37,872,129, 235 genes, copy number 11 (broad region; genes not listed).
- chr20:37,975,156–46,684,467, 220 genes, copy number 10–15 (within-gene range 8–15) (broad region; genes not listed).
- chr21:7,744,962–8,603,984, 27 genes, copy number 10: SMIM11B, FAM243B, SMIM34B, KCNE1B, CU633980.1, FP671120.5, FP671120.4, MIR6724-1, FP671120.1, MIR3648-1, FP671120.2, FP671120.6, RNA5-8SN2, MIR6724-2, FP671120.3, FP671120.7, 5_8S_rRNA, FP236383.3, MIR6724-3, FP236383.1, FP236383.4, RNA5-8SN3, MIR6724-4, FP236383.2, FP236383.5, RNA5-8SN1, RPSAP68.

Autosomal genes at a single copy (total copy number 1): 20. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
